Somatic mutation profile of tumor specimen TCGA-05-4244-01A (aliquot TCGA-05-4244-01A-01D-1105-08) from TCGA case TCGA-05-4244, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.5 years (25,752 days).
Specimen TCGA-05-4244-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3445d00a-6639-4730-b12a-b7f9e225b32c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4244-10A (Blood Derived Normal), aliquot TCGA-05-4244-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2da598c-2663-437d-847b-e0ae228c60fb

The open-access MAF lists 230 somatic variants for this specimen: 183 protein-altering or splice-affecting, 42 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 42, Nonsense Mutation 10, Frame Shift Del 5, Splice Site 5, Frame Shift Ins 3, Splice Region 3, RNA 3, In Frame Del 1, 5'Flank 1, Nonstop Mutation 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABAT | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | catalogued as COSV51628875, COSV99191044; called by muse, mutect2, varscan2
- ABCA13 | c.11954C>T p.S3985F | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs532098587, COSV71287841; called by muse, mutect2, varscan2
- ACACB | c.3021G>T p.M1007I | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV58147996; called by muse, mutect2, varscan2
- ACAN | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61370471; called by muse, mutect2, varscan2
- ADAMTS3 | c.2537C>A p.T846N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV54404288; called by muse, mutect2, varscan2
- ADGRG4 | c.6563T>C p.V2188A | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54968263; called by muse, mutect2, varscan2
- ADGRL3 | c.885C>G p.N295K (on ENST00000506720 / NM_001322402.2; = p.N227K on NM_015236.6) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV72274303; called by muse, mutect2, varscan2
- AHDC1 | c.4073C>T p.T1358I | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs886044186, COSV55942775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMZ1 | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 126/246 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56689296; called by muse, mutect2, varscan2
- ANK1 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs752363656, COSV55880895; called by muse, mutect2, varscan2
- ANXA6 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62908619; called by muse, mutect2, varscan2
- ARHGEF10L | c.2890C>G p.P964A | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.406); catalogued as COSV51441746; called by muse, mutect2
- ARHGEF37 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs969326032, COSV61370507; called by muse, mutect2, varscan2
- ATM | c.7237A>C p.K2413Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV53778560, COSV99589229; called by muse, mutect2, varscan2
- BBS7 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV52659892; called by muse, mutect2, varscan2
- BCHE | c.1241G>C p.R414P | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52262369, COSV52263017; called by muse, mutect2, varscan2
- BCORL1 | c.1988C>G p.S663C | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54408831; called by muse, mutect2, varscan2
- BHMT | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 80/230 reads (35%) | catalogued as COSV57155940; called by mutect2, varscan2
- C16orf71 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV54795169; called by muse, mutect2
- C17orf64 | c.511T>C p.W171R | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1450596616, COSV99293694; called by muse, mutect2, varscan2
- CACNA1C | c.6626T>C p.L2209P (on ENST00000399634 / NM_001167625.1; = p.L2138P on NM_000719.7) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59778206; called by muse, mutect2, varscan2
- CCBE1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV71672616; called by muse, mutect2, varscan2
- CCHCR1 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV52550038; called by muse, mutect2, varscan2
- CDHR5 | c.2454G>C p.E818D (on ENST00000358353 / NM_001171968.2; = p.E824D on NM_021924.5) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs748198900, COSV57646371; called by muse, mutect2, varscan2
- CES1 | c.846G>T p.M282I | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs761773848, COSV62090696; called by muse, mutect2, varscan2
- CFAP221 | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as rs1191133261, COSV54663750; called by muse, mutect2, varscan2
- CHM | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.409); catalogued as COSV62566232; called by muse, mutect2, varscan2
- CHRM3 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 18/271 reads (7%) | catalogued as COSV55106702; called by muse, mutect2
- CHRNB1 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60142555; called by muse, mutect2, varscan2
- CNBD2 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 177/405 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV62588097; called by muse, mutect2, varscan2
- CNTNAP5 | c.2635G>C p.A879P | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70514620; called by muse, mutect2, varscan2
- CPN1 | c.1096C>G p.H366D | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64942883; called by muse, mutect2, varscan2
- CPXM1 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | catalogued as COSV66046899; called by muse, mutect2, varscan2
- CRACD | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV51732780; called by muse, mutect2, varscan2
- CRX | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.496); catalogued as COSV55758727, COSV55760274; called by muse, mutect2, varscan2
- CSMD1 | c.9431G>T p.W3144L (on ENST00000520002; = p.W3143L on NM_033225.6) | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59362577, COSV59391280; called by muse, mutect2, varscan2
- CSRNP3 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 130/486 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV58786450; called by muse, mutect2, varscan2
- CTTNBP2 | c.4611G>T p.M1537I | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV50488885; called by muse, mutect2, varscan2
- DCC | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV59139753; called by muse, mutect2, varscan2
- DCTN5 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV55616609; called by muse, mutect2, varscan2
- DIP2C | c.86-2A>T p.X29_splice | Splice Site (SNP) | VAF 36/173 reads (21%) | catalogued as COSV55181240; called by muse, mutect2, varscan2
- DNAH7 | c.10115G>T p.W3372L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV100414476, COSV56789206; called by muse, mutect2, varscan2
- DOCK7 | c.5962A>T p.I1988F (on ENST00000635253 / NM_001367561.1; = p.I1957F on NM_033407.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.062); catalogued as COSV52022906; called by muse, mutect2, varscan2
- DOCK7 | c.1839G>T p.K613N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV52022931; called by muse, mutect2
- DPF2 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52891594; called by muse, mutect2, varscan2
- DRD1 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs752426861, COSV101192538; called by muse, mutect2, varscan2
- DST | c.19373A>T p.Q6458L (on ENST00000361203 / NM_001374722.1; = p.Q4155L on NM_015548.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); catalogued as COSV55043112; called by muse, mutect2, varscan2
- ECPAS | c.1775A>T p.Y592F | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV52208779; called by muse, mutect2, varscan2
- ENTPD6 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61752543; called by muse, mutect2, varscan2
- EOMES | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767871834, COSV55413919; called by muse, mutect2, varscan2
- EP400 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs546391201, COSV57777277; called by muse, mutect2, varscan2
- ERN2 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56838378; called by muse, mutect2, varscan2
- F13A1 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.58); catalogued as COSV53568591; called by muse, mutect2, varscan2
- FASTKD5 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV53910108; called by muse, mutect2, varscan2
- FAT3 | c.3697C>A p.P1233T | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as COSV53180586; called by muse, mutect2, varscan2
- FGFR4 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as COSV52810618; called by muse, mutect2, varscan2
- FRMPD1 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142418624; called by muse, mutect2, varscan2
- GDF15 | c.756C>A p.N252K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV99416325; called by muse, mutect2, varscan2
- GLIPR1 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs577552703, COSV56993162; called by muse, mutect2, varscan2
- GLP2R | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 168/399 reads (42%) | catalogued as COSV52330066; called by muse, mutect2, varscan2
- GMIP | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs143480494; called by muse, mutect2, varscan2
- GPR156 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 111/411 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59942726; called by muse, mutect2, varscan2
- GRIK2 | c.686A>T p.D229V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59776534; called by muse, mutect2, varscan2
- GRM6 | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.873); catalogued as COSV51450308; called by muse, mutect2, varscan2
- HDAC5 | c.918G>T p.G306= | Splice Region (SNP) | VAF 27/121 reads (22%) | catalogued as COSV56822307; called by muse, mutect2, varscan2
- HECTD2 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV53225305; called by muse, mutect2, varscan2
- HTR6 | c.788C>G p.A263G | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV53877861; called by muse, mutect2, varscan2
- IGHV4-31 | c.204G>C p.W68C | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs1211762430; called by muse, mutect2, varscan2
- ITIH4 | c.1046-2A>C p.X349_splice | Splice Site (SNP) | VAF 52/330 reads (16%) | catalogued as COSV56579350; called by muse, mutect2, varscan2
- KAT2B | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV55435220; called by muse, mutect2, varscan2
- KCNH6 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as COSV59005475; called by muse, mutect2, varscan2
- KCNH7 | c.2885C>A p.A962E | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs183477423, COSV59793559, COSV59815396; called by muse, mutect2, varscan2
- KCNS2 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV54641351; called by muse, mutect2, varscan2
- KDM5C | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 54/117 reads (46%) | catalogued as COSV64766023; called by muse, mutect2, varscan2
- KLHL38 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.102); catalogued as rs911187287, COSV58089397; called by muse, mutect2, varscan2
- KLK7 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100304513; called by muse, mutect2, varscan2
- KNL1 | c.3098G>T p.R1033L (on ENST00000346991 / NM_170589.5; = p.R1007L on NM_144508.5) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV61160939; called by muse, mutect2, varscan2
- KRTAP21-2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV100441293; called by muse, mutect2, varscan2
- LACRT | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as COSV57688877; called by muse, mutect2, varscan2
- LAMA4 | c.3932T>A p.L1311Q (on ENST00000230538 / NM_001105206.3; = p.L1304Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV57905862; called by muse, mutect2, varscan2
- LEXM | c.859C>G p.R287G | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64024402; called by muse, mutect2, varscan2
- LHCGR | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV54303900, COSV99683666; called by muse, mutect2, varscan2
- LUC7L3 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV53589785; called by muse, mutect2, varscan2
- MPC1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV100515581; called by muse, mutect2, varscan2
- MUC16 | c.18821G>T p.R6274L | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV67497597; called by muse, mutect2, varscan2
- MYH2 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55449887; called by muse, mutect2, varscan2
- MYH7 | c.4772T>A p.L1591Q | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs730880808, CM124961, CM1413450, COSV62524609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NALCN | c.3702G>T p.E1234D | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99218198; called by muse, mutect2, varscan2
- NALCN | c.3701A>T p.E1234V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99218203; called by muse, mutect2, varscan2
- NEIL1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV61834258; called by muse, mutect2, varscan2
- NKX2-5 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV61300060; called by muse, mutect2, varscan2
- NR0B2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99575092; called by muse, mutect2, varscan2
- OR10K2 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs938785060, COSV59222961; called by muse, mutect2
- OR10Q1 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV57471964, COSV57472128; called by muse, mutect2, varscan2
- OR13D1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59515189; called by muse, mutect2, varscan2
- OR1A1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1486490338, COSV100410843; called by muse, mutect2, varscan2
- OR1K1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52956194, COSV99474390; called by muse, mutect2, varscan2
- OR2A5 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68739218; called by muse, mutect2, varscan2
- OR2B3 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013865, COSV65851186; called by muse, mutect2, varscan2
- OR2L2 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as COSV63562204; called by muse, mutect2, varscan2
- OR4S2 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 100/147 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100412840; called by muse, mutect2, varscan2
- OTOP1 | c.672C>A p.H224Q | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99588222; called by muse, mutect2, varscan2
- PABPC3 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV99880177; called by muse, mutect2, varscan2
- PCDH11X | c.3024C>G p.H1008Q | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV53509077; called by muse, mutect2, varscan2
- PCDHB11 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV53384425; called by muse, mutect2, varscan2
- PCDHB7 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); catalogued as rs148889209; called by muse, mutect2, varscan2
- PCDHB9 | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53384419, COSV53384952; called by muse, mutect2, varscan2
- PCDHGA5 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV54043856; called by muse, mutect2, varscan2
- PEBP1 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54336871, COSV54337969; called by muse, mutect2, varscan2
- PIP4P2 | c.107-1G>C p.X36_splice | Splice Site (SNP) | VAF 29/140 reads (21%) | catalogued as COSV53441171; called by muse, mutect2, varscan2
- PIRT | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV101652691; called by muse, mutect2, varscan2
- PLG | c.1264A>T p.T422S | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV51986824; called by muse, mutect2, varscan2
- POLA1 | c.3572G>A p.R1191K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66891216; called by muse, mutect2, varscan2
- POLR3G | c.*156G>C | Splice Region (SNP) | VAF 15/91 reads (16%) | catalogued as COSV101209846; called by muse, mutect2, varscan2
- PRDM9 | c.2476C>A p.H826N | Missense Mutation (SNP) | VAF 115/430 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57014058; called by muse, varscan2
- PREX2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99910407; called by muse, mutect2, varscan2
- PRPF38A | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV57123430; called by muse, mutect2, varscan2
- PRPF40A | c.2318A>T p.E773V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.978); catalogued as COSV101344242, COSV68356394; called by muse, mutect2, varscan2
- PRR23B | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs780056975, COSV100272239, COSV61494784; called by muse, mutect2, varscan2
- PRSS12 | c.1840T>C p.S614P | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56610922; called by muse, varscan2
- PRSS38 | c.385T>A p.W129R | Missense Mutation (SNP) | VAF 116/184 reads (63%) | SIFT tolerated (0.7); PolyPhen benign (0.334); catalogued as COSV64542090; called by muse, mutect2, varscan2
- PTPN3 | c.2673C>G p.Y891* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV52711618; called by muse, mutect2, varscan2
- PTPRT | c.1345C>A p.L449M | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV61981299, COSV62026471; called by muse, mutect2, varscan2
- PTPRT | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62026485; called by muse, mutect2, varscan2
- PYCR2 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); catalogued as COSV59525560; called by muse, mutect2
- RABGAP1L | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99274767; called by muse, mutect2, varscan2
- RC3H2 | c.3240G>T p.L1080F | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as COSV61802758; called by muse, mutect2, varscan2
- REXO1 | c.3368G>A p.R1123H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs142299409; called by muse, mutect2, varscan2
- ROBO2 | c.2884G>T p.D962Y | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV59901655; called by muse, mutect2, varscan2
- RP1 | c.5299G>T p.A1767S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.165); catalogued as COSV55128139; called by muse, mutect2, varscan2
- RP1 | c.5565G>T p.K1855N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV55128148; called by muse, mutect2, varscan2
- RPL10L | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV100022794, COSV53559550; called by muse, mutect2, varscan2
- RSPH10B2 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786421; called by mutect2, varscan2
- RTTN | c.2886-2A>T p.X962_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55352867; called by muse, mutect2, varscan2
- SCN9A | c.2522G>C p.R841P (on ENST00000303354; = p.R830P on NM_002977.3) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57626671; called by muse, mutect2, varscan2
- SDSL | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1026898370, COSV61885451; called by muse, mutect2, varscan2
- SLC1A6 | c.1693T>A p.*565Rext*? | Nonstop Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV55671003, COSV55674626; called by muse, mutect2, varscan2
- SLX4 | c.4668del p.V1558Cfs*3 | Frame Shift Del (DEL) | VAF 67/487 reads (14%) | catalogued as rs752736478; called by mutect2, pindel, varscan2
- SMG1 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV67175084; called by muse, mutect2, varscan2
- SPAM1 | c.1056G>T p.L352F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs1190830788, COSV56148426; called by muse, varscan2
- SPPL2A | c.1163G>T p.R388I | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55942747, COSV55943494; called by muse, mutect2, varscan2
- SPTA1 | c.2908G>C p.A970P | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100935549, COSV63760509; called by muse, mutect2, varscan2
- TCF23 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99940440; called by muse, mutect2, varscan2
- TCHHL1 | c.1988A>G p.E663G | Missense Mutation (SNP) | VAF 40/583 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV64286730; called by muse, mutect2
- TEX55 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.083); catalogued as rs559349551, COSV55213058, COSV99817764; called by muse, mutect2, varscan2
- TFRC | c.632A>C p.Y211S | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV64056875; called by muse, mutect2, varscan2
- TMEM132B | c.1183G>T p.V395L | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV54772332; called by muse, mutect2, varscan2
- TNRC6A | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.857); catalogued as COSV59370697; called by mutect2, varscan2
- TNS2 | c.1529G>T p.S510I (on ENST00000314250 / NM_170754.4; = p.S520I on NM_015319.2) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV58582467; called by muse, mutect2, varscan2
- TNS4 | c.680A>T p.N227I | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV54188410; called by muse, mutect2, varscan2
- TRIM71 | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV67472838; called by muse, mutect2, varscan2
- TRIM9 | c.1293C>A p.F431L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV53625623; called by muse, mutect2, varscan2
- TRPC3 | c.1149A>T p.K383N (on ENST00000379645 / NM_001366479.2; = p.K310N on NM_003305.2) | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV53382176; called by muse, mutect2, varscan2
- TRPM1 | c.2505+1G>C p.X835_splice | Splice Site (SNP) | VAF 38/132 reads (29%) | catalogued as COSV56643388; called by muse, mutect2, varscan2
- TRPM2 | c.2881C>A p.R961S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV55977992; called by muse, varscan2
- TSHZ1 | c.1822G>T p.G608C (on ENST00000580243 / NM_001308210.2; = p.G563C on NM_005786.6) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV59017893, COSV59018131; called by muse, mutect2, varscan2
- TTC39C | c.691T>A p.S231T (on ENST00000317571 / NM_001135993.2; = p.S170T on NM_153211.4) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58221506; called by muse, mutect2, varscan2
- UBE2J1 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV70562632; called by muse, varscan2
- VPS13A | c.3812G>T p.R1271I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62440143; called by muse, mutect2, varscan2
- VPS13C | c.4875T>C p.H1625= (on ENST00000644861 / NM_020821.3; = p.H1582= on NM_017684.5) | Splice Region (SNP) | VAF 13/56 reads (23%) | catalogued as COSV51427549; called by muse, mutect2, varscan2
- WDR72 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1200122301, COSV64754505; called by muse, mutect2, varscan2
- WRN | c.3207G>T p.L1069F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV53308173; called by muse, mutect2, varscan2
- ZFHX4 | c.4039G>T p.E1347* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV50683097; called by muse, mutect2, varscan2
- ZIC4 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.343); catalogued as rs1411380137, COSV101268175; called by muse, mutect2, varscan2
- ZMAT5 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100722680; called by muse, mutect2, varscan2
- ZNF10 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1033505099, COSV50215519; called by muse, mutect2, varscan2
- ZNF423 | c.1704G>A p.M568I (on ENST00000563137 / NM_001379286.1; = p.M560I on NM_015069.4) | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV52206098; called by muse, mutect2, varscan2
- ZNF430 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV99842097; called by muse, mutect2, varscan2
- ZNF676 | c.944G>A p.C315Y (on ENST00000650058; = p.C283Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68095167; called by muse, mutect2, varscan2
- ZNF711 | c.496A>T p.N166Y | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV52159536; called by muse, mutect2, varscan2
- ZNF83 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1175299078, COSV99991610; called by muse, mutect2, varscan2
- CDK12 | c.92_101del p.N31Sfs*23 | Frame Shift Del (DEL) | VAF 35/181 reads (19%) | called by mutect2, pindel, varscan2
- CYB561A3 | c.127_145del p.M43Cfs*40 | Frame Shift Del (DEL) | VAF 75/340 reads (22%) | called by mutect2, pindel, varscan2
- FAM131B | c.764dup p.D256Rfs*3 | Frame Shift Ins (INS) | VAF 56/300 reads (19%) | called by mutect2, pindel, varscan2
- GBP4 | c.75dup p.I26Hfs*22 | Frame Shift Ins (INS) | VAF 31/160 reads (19%) | called by mutect2, pindel, varscan2
- IARS2 | c.230del p.G77Afs*29 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- IGKV1D-16 | c.161G>C p.W54S | Missense Mutation (SNP) | VAF 94/432 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR1 | c.4016del p.G1339Efs*17 (on ENST00000354582; = p.G1324Efs*17 on NM_002222.7) | Frame Shift Del (DEL) | VAF 72/440 reads (16%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, varscan2
- MCM7 | c.522dup p.P175Tfs*11 | Frame Shift Ins (INS) | VAF 34/138 reads (25%) | called by mutect2, pindel, varscan2
- NEBL | c.2189_2194del p.S730_V731del | In Frame Del (DEL) | VAF 30/131 reads (23%) | called by mutect2, pindel, varscan2
- TRAC | c.398T>A p.L133H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACOX3 | c.699G>T p.P233= | Silent (SNP) | VAF 67/263 reads (25%) | catalogued as COSV62712778, COSV62713949; called by muse, mutect2, varscan2
- ACTR3 | c.927T>A p.I309= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV54304488; called by mutect2, varscan2
- ADAMTS20 | c.1335C>T p.N445= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV67140499; called by muse, mutect2, varscan2
- AMER3 | c.1509C>A p.A503= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV58470737; called by muse, mutect2, varscan2
- ANAPC7 | c.765C>T p.I255= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV71444080; called by muse, mutect2, varscan2
- ANK2 | c.5757C>A p.S1919= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV52191748; called by muse, mutect2, varscan2
- APOL5 | c.949C>T p.L317= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV99968486; called by muse, mutect2, varscan2
- BRINP3 | c.690G>T p.L230= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV66542832; called by muse, mutect2, varscan2
- C17orf98 | c.396C>T p.R132= | Silent (SNP) | VAF 36/197 reads (18%) | called by muse, mutect2, varscan2
- C6 | c.1491C>A p.I497= | Silent (SNP) | VAF 75/233 reads (32%) | catalogued as rs1203420130, COSV54719999; called by muse, mutect2, varscan2
- CACNA1S | c.3465G>T p.V1155= | Silent (SNP) | VAF 75/157 reads (48%) | catalogued as COSV62936888; called by muse, mutect2, varscan2
- COL3A1 | c.3123T>A p.G1041= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV58597535; called by muse, mutect2, varscan2
- CPEB1 | c.1698T>A p.I566= (on ENST00000617958; = p.I501= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as COSV55622009; called by muse, mutect2, varscan2
- CYP4F2 | c.1428G>A p.A476= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV55616254; called by muse, mutect2, varscan2
- DUS3L | c.705C>T p.F235= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100288341, COSV57833844; called by muse, varscan2
- ERCC6 | c.4143C>T p.S1381= | Silent (SNP) | VAF 88/334 reads (26%) | catalogued as rs375921453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERN2 | c.333G>A p.L111= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs369299952; called by muse, mutect2, varscan2
- GIMAP8 | c.768C>T p.R256= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as rs772655799, COSV56234498; called by muse, mutect2, varscan2
- IRGC | c.195G>A p.A65= | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as rs372095741; called by muse, mutect2, varscan2
- KCNH5 | c.108G>T p.V36= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV59779969; called by muse, mutect2, varscan2
- KYNU | c.228T>G p.L76= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99934122; called by muse, varscan2
- L3HYPDH | c.981A>G p.V327= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as rs961489221, COSV55967916; called by muse, mutect2, varscan2
- LRTM2 | c.1005C>T p.Y335= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs750674817, COSV54564397; called by muse, mutect2, varscan2
- MKI67 | c.7203C>T p.N2401= | Silent (SNP) | VAF 15/412 reads (4%) | catalogued as COSV64077341; called by muse, mutect2
- NEB | c.12198C>A p.I4066= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1310753005, COSV51464217; called by muse, mutect2, varscan2
- OR14C36 | c.279G>C p.A93= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV58602982; called by muse, mutect2, varscan2
- OR2A14 | c.42G>A p.P14= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs1405663096, COSV68718116; called by muse, mutect2, varscan2
- OR3A3 | c.312C>T p.D104= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs567381667, COSV99351591; called by mutect2, varscan2
- OR4S2 | c.666C>A p.S222= | Silent (SNP) | VAF 99/145 reads (68%) | catalogued as COSV100412839; called by muse, mutect2, varscan2
- PHGDH | c.237T>A p.G79= | Silent (SNP) | VAF 29/265 reads (11%) | catalogued as COSV65572733; called by muse, mutect2, varscan2
- PSG8 | c.1257A>C p.P419= | Silent (SNP) | VAF 108/407 reads (27%) | catalogued as COSV60616354; called by muse, mutect2, varscan2
- RAPSN | c.771G>T p.R257= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100100433; called by muse, mutect2, varscan2
- RTN1 | c.1917C>T p.R639= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV50738304, COSV50752693; called by muse, mutect2, varscan2
- SERPINA3 | c.1125C>T p.A375= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as COSV67587292; called by muse, mutect2, varscan2
- SFXN1 | c.312A>T p.T104= | Silent (SNP) | VAF 89/396 reads (22%) | catalogued as COSV58495376; called by muse, mutect2, varscan2
- SLCO1B1 | c.1872C>A p.V624= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57018096; called by muse, mutect2, varscan2
- TEAD3 | c.588C>A p.L196= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs377340899; called by muse, mutect2
- TLL2 | c.549C>A p.A183= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV63576379; called by muse, mutect2, varscan2
- TTLL4 | c.1098C>T p.P366= | Silent (SNP) | VAF 46/211 reads (22%) | catalogued as COSV51439824; called by muse, mutect2, varscan2
- UGT2B4 | c.354A>T p.T118= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV59321126; called by muse, mutect2
- USP7 | c.2955G>A p.E985= | Silent (SNP) | VAF 77/794 reads (10%) | catalogued as COSV61217819; called by muse, mutect2
- ZBED4 | c.3480G>A p.L1160= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV53468480; called by muse, mutect2, varscan2
- CLLU1 | n.897C>A | RNA (SNP) | VAF 11/44 reads (25%) | catalogued as rs369773459, COSV101029275; called by muse, mutect2, varscan2
- DIO3 | chr14:101560329 C>A | 5'Flank (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- SNORD115-40 | n.61C>A | RNA (SNP) | VAF 197/664 reads (30%) | called by muse, mutect2, varscan2
- SSPOP | n.13478G>C | RNA (SNP) | VAF 6/29 reads (21%) | catalogued as COSV65138238; called by muse, mutect2, varscan2
- Unknown | chr21:16071192 del G | IGR (DEL) | VAF 62/332 reads (19%) | called by mutect2, pindel, varscan2
